Somatic mutation profile of tumor specimen C3L-02619-01 (aliquot CPT0191860006) from CPTAC case C3L-02619, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 70.2 years (25,633 days).
Specimen C3L-02619-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdb268a4-df45-458e-9fff-bb49a03beea8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02619-31 (Blood Derived Normal), aliquot CPT0192020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab091184-9672-4b37-9a27-f34d2e6cc664

The open-access MAF lists 343 somatic variants for this specimen: 203 protein-altering or splice-affecting, 97 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 97, Nonsense Mutation 13, 3'UTR 12, Intron 12, RNA 8, 5'UTR 7, 5'Flank 4, Splice Site 3, Frame Shift Del 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+2T>A p.X307_splice | Splice Site (SNP) | VAF 280/812 reads (34%) | hotspot (GDC flag); catalogued as rs1131691016, COSV52698436, COSV52737448, COSV52774697; ClinVar: pathogenic; called by mutect2, varscan2
- ACSM2A | c.240G>T p.M80I (on ENST00000219054; = p.M1? on NM_001308169.2) | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1349662791, COSV54587055; called by muse, varscan2
- ACVR1C | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as rs1192513314; called by muse, mutect2, varscan2
- ADAT3 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs751800354; called by muse, mutect2, varscan2
- ADGRB1 | c.3592C>T p.R1198C | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1272145393; called by muse, mutect2, varscan2
- ANK1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 72/758 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs770353869, COSV55883097; ClinVar: uncertain significance; called by muse, mutect2
- ARMC4 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as rs587777199, CM140049; called by muse, mutect2
- C7 | c.2269C>A p.L757I | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV100496324; called by muse, mutect2, varscan2
- CACNA1H | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.123); catalogued as rs1303029428; called by muse, mutect2, varscan2
- CACNA1I | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 45/505 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1428316723; called by muse, mutect2
- CAD | c.4579G>A p.A1527T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs751940560, COSV53030210, COSV53032962; called by muse, mutect2, varscan2
- CORO6 | c.451+1G>T p.X151_splice | Splice Site (SNP) | VAF 29/123 reads (24%) | catalogued as rs371000206; called by muse, mutect2, varscan2
- CPNE9 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 96/512 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.094); catalogued as rs1559632994; called by muse, varscan2
- CPT1B | c.1948G>T p.G650W | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56416816; called by muse, mutect2, varscan2
- CRELD2 | c.683G>C p.C228S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58207226; called by muse, mutect2, varscan2
- CSMD1 | c.5379C>A p.N1793K (on ENST00000520002; = p.N1792K on NM_033225.6) | Missense Mutation (SNP) | VAF 67/391 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769926696; called by muse, mutect2, varscan2
- CUBN | c.5323C>T p.R1775W | Missense Mutation (SNP) | VAF 99/477 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1276708; called by muse, mutect2, varscan2
- CYP2C19 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs1258763803; called by muse, mutect2, varscan2
- DCC | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1186851421, COSV59114706; called by muse, mutect2, varscan2
- DNAH6 | c.3334G>C p.E1112Q | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs77290709; called by muse, mutect2
- DNER | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); catalogued as rs772555280, COSV59162827; called by muse, mutect2
- DRAXIN | c.680C>G p.T227R | Missense Mutation (SNP) | VAF 87/383 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53841944; called by muse, mutect2, varscan2
- E2F8 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778630321; called by muse, mutect2, varscan2
- ERBB4 | c.3285G>T p.Q1095H | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV61510820; called by muse, mutect2, varscan2
- ERICH3 | c.2189T>C p.L730S | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.506); catalogued as COSV58610213; called by muse, mutect2
- FBN2 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs1357709072; called by muse, mutect2, varscan2
- FLI1 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 121/433 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV55644605; called by muse, mutect2, varscan2
- FOXO3 | c.1850A>G p.N617S | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.044); catalogued as rs761885562; called by muse, mutect2, varscan2
- FRK | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1461759452; called by muse, mutect2, varscan2
- GAB4 | c.1490del p.A497Dfs*34 | Frame Shift Del (DEL) | VAF 82/382 reads (21%) | catalogued as COSV101271914; called by mutect2, pindel, varscan2
- GPS2 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 43/382 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV59750540; called by muse, mutect2, varscan2
- GRM6 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as rs138843463; called by muse, varscan2
- HERC1 | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs773366677; called by mutect2, varscan2
- IGKV3-20 | c.153C>A p.S51R | Missense Mutation (SNP) | VAF 82/650 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs372380677; called by muse, mutect2, varscan2
- ILDR2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs937233990, COSV54833776; called by muse, mutect2, varscan2
- JAKMIP1 | c.1082C>G p.T361R | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV51523487; called by muse, mutect2, varscan2
- KCNMB1 | c.159C>A p.C53* | Nonsense Mutation (SNP) | VAF 54/232 reads (23%) | catalogued as rs147511146; called by muse, mutect2, varscan2
- KCNT2 | c.3308G>T p.R1103L | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54075788, COSV99651618; called by muse, mutect2, varscan2
- KIAA2026 | c.4858A>G p.T1620A | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs759067525; called by muse, mutect2, varscan2
- KIF1A | c.2593C>A p.P865T | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV57487471; called by muse, mutect2
- KIF5B | c.2323C>T p.R775* | Nonsense Mutation (SNP) | VAF 16/184 reads (9%) | catalogued as COSV56652547; called by muse, mutect2
- KPNA7 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 53/644 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1395088843, COSV59399535; called by muse, mutect2
- LAMA1 | c.7735A>G p.S2579G | Missense Mutation (SNP) | VAF 132/449 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as COSV67535184; called by muse, mutect2, varscan2
- LIMS2 | c.822G>T p.K274N (on ENST00000355119 / NM_001161403.3; = p.K298N on NM_017980.4) | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs571756830; called by muse, mutect2
- LRRN2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141763834; called by muse, mutect2, varscan2
- LSM14B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99443622; called by muse, mutect2
- LTB4R | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 91/455 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775121660; called by muse, mutect2, varscan2
- MALRD1 | c.6137G>T p.R2046L | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.722); catalogued as COSV65978065; called by muse, mutect2, varscan2
- MCOLN3 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV62016478; called by muse, mutect2
- MTAP | c.372C>G p.F124L | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as rs769325198, COSV66476859; called by muse, varscan2
- NCKAP5L | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258517; called by muse, mutect2, varscan2
- NKPD1 | c.2283C>A p.S761R | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.127); catalogued as COSV55524700; called by muse, mutect2, varscan2
- NOTCH4 | c.887A>G p.D296G | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs757766765; called by muse, mutect2
- NSUN3 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 81/238 reads (34%) | catalogued as rs199659889; called by muse, mutect2, varscan2
- NT5DC1 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.129); catalogued as rs757924218, COSV100127150, COSV100127238; called by muse, mutect2, varscan2
- OR2G2 | c.361A>T p.M121L | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100189990; called by muse, mutect2, varscan2
- OTX1 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 97/431 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99246475; called by muse, mutect2, varscan2
- PDZD7 | c.484A>G p.M162V | Missense Mutation (SNP) | VAF 108/392 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs568624029; called by muse, mutect2, varscan2
- PGM5 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67164456; called by muse, mutect2, varscan2
- PPP4R3C | c.2177C>T p.T726M | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs779418333, COSV69080742; called by muse, mutect2, varscan2
- PRKD1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760459161; called by muse, mutect2, varscan2
- PSMD5 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as COSV52960703; called by muse, mutect2
- RGL1 | c.626C>T p.T209M (on ENST00000360851 / NM_001297672.2; = p.T244M on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs145145034; called by muse, mutect2
- RNF31 | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 85/433 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53760356; called by muse, mutect2, varscan2
- SACS | c.7150G>A p.E2384K | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs762896797, COSV66543934; ClinVar: uncertain significance; called by muse, mutect2
- SCN11A | c.2618G>T p.C873F | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56579478; called by muse, mutect2, varscan2
- SDSL | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774776829; called by muse, mutect2, varscan2
- SEMA5B | c.2657G>T p.R886L | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV52109459; called by muse, mutect2, varscan2
- SGSM2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 140/603 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs759646093, COSV99280061; called by muse, mutect2, varscan2
- SI | c.4165G>T p.D1389Y | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52294882; called by muse, mutect2, varscan2
- SLC23A1 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268732360; called by muse, mutect2, varscan2
- SLC26A1 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 72/430 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs1239894630; called by muse, mutect2, varscan2
- SYNPO | c.1491G>T p.Q497H (on ENST00000394243 / NM_001166208.2; = p.Q253H on NM_007286.6) | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99059830; called by muse, mutect2, varscan2
- TEX15 | c.7210C>A p.P2404T (on ENST00000256246; = p.P2787T on NM_001350162.2) | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs778946377, COSV56355257; called by muse, mutect2, varscan2
- TMEM176B | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs779969970, COSV100423817; called by muse, mutect2
- TTN | c.67400G>A p.G22467D (on ENST00000591111; = p.G15043D on NM_003319.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | PolyPhen probably damaging (1); catalogued as rs1056756805; called by muse, mutect2, varscan2
- UQCC1 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 56/422 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs371771638; called by muse, mutect2, varscan2
- VAT1L | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs373719090; called by muse, mutect2
- VMP1 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs1171013928, COSV99230674; called by muse, mutect2, varscan2
- ZIC4 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 48/599 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.461); catalogued as COSV67171709; called by muse, mutect2
- ZNF676 | c.1600G>T p.E534* (on ENST00000650058; = p.E502* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 70/320 reads (22%) | catalogued as COSV101236074; called by muse, mutect2, varscan2
- ZNF800 | c.223del p.R75Afs*10 | Frame Shift Del (DEL) | VAF 21/135 reads (16%) | catalogued as COSV56175067, COSV99757947; called by mutect2, pindel, varscan2
- ZNF804A | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100169189; called by muse, mutect2
- ZNF814 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as rs747675766; called by muse, mutect2, varscan2
- ABCB10 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AC068633.1 | n.217-1G>T | Splice Site (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.1038C>A p.H346Q | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- ADCY8 | c.3352G>T p.A1118S | Missense Mutation (SNP) | VAF 188/446 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF2 | c.3135G>T p.W1045C | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANXA6 | c.1954G>C p.A652P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.648); called by mutect2, varscan2
- BBS10 | c.1866T>A p.H622Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BRINP1 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- BZW1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- C2orf69 | c.160T>A p.C54S | Missense Mutation (SNP) | VAF 96/438 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- C6orf132 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C8orf88 | c.115A>G p.N39D | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPN9 | c.362A>T p.Q121L | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CAPRIN2 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 31/408 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2
- CARF | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CATSPERD | c.460C>A p.H154N | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH9 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 75/556 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CEP170 | c.3962G>C p.G1321A | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP20DC | c.1225G>T p.G409C (on ENST00000482387 / NM_001351530.2; = p.G284C on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFHR4 | c.1349G>T p.C450F (on ENST00000367416 / NM_001201551.2; = p.C204F on NM_006684.5) | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIITA | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 142/560 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CISH | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNGA3 | c.216-4C>G | Splice Region (SNP) | VAF 54/391 reads (14%) | called by muse, mutect2, varscan2
- COLEC12 | c.1839C>A p.N613K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CPS1 | c.2702A>G p.E901G | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.049); called by muse, mutect2
- CPT1C | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 25/250 reads (10%) | called by muse, mutect2
- CSMD3 | c.7895G>T p.C2632F (on ENST00000297405 / NM_001363185.1; = p.C2528F on NM_052900.3) | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYFIP2 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DPP9 | c.2311A>G p.M771V (on ENST00000598800; = p.M800V on NM_139159.5) | Missense Mutation (SNP) | VAF 103/504 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- DTNA | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 83/400 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- DZIP3 | c.1516T>C p.C506R | Missense Mutation (SNP) | VAF 38/443 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- FAM171B | c.1751A>C p.Q584P | Missense Mutation (SNP) | VAF 39/371 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FREM3 | c.4726A>C p.I1576L | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2
- FREM3 | c.4724C>A p.T1575N | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2
- FREM3 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GALNT3 | c.400A>T p.S134C | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- GIMAP1 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GOLGA6B | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 74/1490 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.202); called by muse, mutect2
- GRHL2 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 70/521 reads (13%) | called by muse, mutect2, varscan2
- H3C10 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 23/250 reads (9%) | called by muse, mutect2
- HAO1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- HNRNPCL2 | c.756C>G p.D252E | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HTR1A | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 158/611 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HYDIN | c.2321G>C p.G774A | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV3D-7 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 26/353 reads (7%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ITPR3 | c.6487G>A p.E2163K | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- KBTBD3 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KCND3 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 112/465 reads (24%) | SIFT tolerated, low confidence (0.78); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- KCNJ8 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 137/530 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KCNMA1 | c.813G>C p.L271F | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2
- KCNQ5 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KCNQ5 | c.2371G>T p.V791F | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KLRF1 | c.293G>C p.S98T | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LAT | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LIMS2 | c.820A>C p.K274Q (on ENST00000355119 / NM_001161403.3; = p.K298Q on NM_017980.4) | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LOX | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 64/271 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- LTBP3 | c.3268G>T p.A1090S | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAGEL2 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- MAPKAPK3 | c.103A>C p.K35Q | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- MAS1 | c.717C>G p.I239M | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2
- MAX | c.146C>G p.S49* | Nonsense Mutation (SNP) | VAF 52/455 reads (11%) | called by muse, mutect2, varscan2
- MC3R | c.595A>G p.M199V | Missense Mutation (SNP) | VAF 67/796 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- MDGA1 | c.821A>T p.Q274L | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKRN3 | c.253A>T p.S85C | Missense Mutation (SNP) | VAF 68/327 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- MLLT10 | c.1297T>A p.F433I | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MTR | c.3757G>C p.E1253Q | Missense Mutation (SNP) | VAF 48/534 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2
- MYH2 | c.4724A>T p.K1575M | Missense Mutation (SNP) | VAF 89/339 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MYH8 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 115/508 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NAV1 | c.3206C>G p.S1069C | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOVA1 | c.1016C>G p.A339G | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NPL | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 80/722 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUTM2G | c.2004A>T p.K668N | Missense Mutation (SNP) | VAF 138/644 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NYNRIN | c.5212del p.A1738Rfs*24 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- OGFR | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 33/378 reads (9%) | called by muse, mutect2
- ONECUT1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2
- OR11H1 | c.897G>C p.K299N | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by mutect2, varscan2
- OR2L3 | c.770C>A p.T257N | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- OR2T33 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 64/1190 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2
- OR2T8 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OR51S1 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.383); called by muse, varscan2
- OR8B8 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OTOL1 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 163/379 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAH | c.543G>C p.E181D | Missense Mutation (SNP) | VAF 83/346 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARG | c.1208A>G p.H403R | Missense Mutation (SNP) | VAF 65/363 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PCDHA5 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 87/312 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- PDZD4 | c.178A>T p.S60C | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- PLCL2 | c.2848C>T p.L950F (on ENST00000615277 / NM_001144382.2; = p.L824F on NM_015184.5) | Missense Mutation (SNP) | VAF 75/310 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PPP2R5C | c.1146G>A p.W382* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- PTPN23 | c.159G>A p.Q53= | Splice Region (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- RAD17 | c.940A>G p.I314V (on ENST00000380774 / NM_133339.2; = p.I303V on NM_002873.1) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RBM46 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RCOR1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RFX4 | c.1216G>A p.D406N (on ENST00000392842 / NM_213594.3; = p.D312N on NM_032491.6) | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- RNASET2 | c.100T>C p.W34R | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR1 | c.10403C>T p.S3468F | Missense Mutation (SNP) | VAF 144/504 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- SCGN | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHARPIN | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.726); called by muse, mutect2
- SLAMF1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 50/475 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC9A3R1 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 110/468 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC9C1 | c.2992T>C p.W998R | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPACA7 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- SPTLC1 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRPK1 | c.1096A>T p.T366S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.5321C>T p.S1774F | Missense Mutation (SNP) | VAF 158/586 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TBX3 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 53/473 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TDRD15 | c.1400T>A p.L467* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- TENM1 | c.968C>G p.A323G | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- TESPA1 | c.817G>C p.E273Q (on ENST00000316577 / NM_001098815.3; = p.E135Q on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TEX15 | c.7211C>T p.P2404L (on ENST00000256246; = p.P2787L on NM_001350162.2) | Missense Mutation (SNP) | VAF 60/316 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM39A | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- TRDN | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 54/407 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- TRIO | c.3661G>C p.V1221L | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TSPO | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- UGT2A2 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2
- USH2A | c.1154T>A p.I385N | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- USP34 | c.7895G>C p.W2632S | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZBTB18 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF608 | c.188A>T p.K63M | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- ZNF626 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ABCB7 | c.2253G>A p.S751= (on ENST00000373394 / NM_001271696.3; = p.S752= on NM_004299.6) | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs771854345, COSV53720982, COSV53724260; called by muse, varscan2
- AC127029.3 | c.669C>T p.G223= | Silent (SNP) | VAF 66/585 reads (11%) | catalogued as rs143833877; called by muse, mutect2, varscan2
- ADCY8 | c.3351G>T p.L1117= | Silent (SNP) | VAF 182/438 reads (42%) | called by muse, mutect2, varscan2
- ADGB | c.1491A>G p.L497= | Silent (SNP) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- ADGRB3 | c.1707A>G p.S569= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as COSV65382134; called by muse, mutect2, varscan2
- ADGRL1 | c.3150G>A p.A1050= (on ENST00000340736 / NM_001008701.3; = p.A1045= on NM_014921.5) | Silent (SNP) | VAF 34/237 reads (14%) | catalogued as rs756943008, COSV61565268; called by muse, mutect2, varscan2
- ADO | c.561G>T p.P187= | Silent (SNP) | VAF 96/442 reads (22%) | called by muse, mutect2, varscan2
- AKNA | c.4248C>T p.T1416= | Silent (SNP) | VAF 47/201 reads (23%) | called by muse, mutect2, varscan2
- ANKRD31 | c.909C>A p.T303= | Silent (SNP) | VAF 45/177 reads (25%) | called by muse, mutect2, varscan2
- CA1 | c.510C>T p.T170= | Silent (SNP) | VAF 64/278 reads (23%) | called by muse, mutect2, varscan2
- CARD11 | c.2235C>A p.G745= | Silent (SNP) | VAF 81/249 reads (33%) | catalogued as rs762649933; called by muse, mutect2, varscan2
- CARMIL1 | c.696T>C p.T232= | Silent (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- CCDC57 | c.2256C>T p.A752= | Silent (SNP) | VAF 25/255 reads (10%) | catalogued as rs746137809; called by muse, mutect2, varscan2
- CCDC63 | c.1071C>A p.I357= | Silent (SNP) | VAF 47/212 reads (22%) | catalogued as COSV100370356; called by muse, mutect2, varscan2
- CCDC96 | c.249G>T p.G83= | Silent (SNP) | VAF 24/241 reads (10%) | called by muse, mutect2, varscan2
- CDADC1 | c.486G>A p.T162= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs146260810; called by muse, mutect2, varscan2
- CHRDL1 | c.9C>A p.G3= (on ENST00000372045; = p.G9= on NM_145234.4) | Silent (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- DLC1 | c.1156C>T p.L386= | Silent (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- DMRTB1 | c.945T>A p.T315= | Silent (SNP) | VAF 88/293 reads (30%) | called by muse, mutect2, varscan2
- DNAAF1 | c.1566C>T p.F522= | Silent (SNP) | VAF 56/506 reads (11%) | catalogued as rs1472474428, COSV57578558; called by muse, mutect2, varscan2
- DNAH3 | c.1095C>T p.L365= | Silent (SNP) | VAF 22/253 reads (9%) | called by muse, mutect2
- DNHD1 | c.7512C>T p.V2504= | Silent (SNP) | VAF 28/285 reads (10%) | catalogued as rs1479864842; called by muse, mutect2, varscan2
- DOCK4 | c.4026C>T p.Y1342= | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as rs137868719; called by muse, mutect2, varscan2
- DRC3 | c.1092G>A p.A364= | Silent (SNP) | VAF 30/271 reads (11%) | catalogued as rs768136853, COSV100572708; called by muse, mutect2, varscan2
- EFR3B | c.2268C>T p.F756= | Silent (SNP) | VAF 47/448 reads (10%) | catalogued as rs1468223932, COSV53121947; called by muse, mutect2
- EFTUD2 | c.1785C>G p.V595= | Silent (SNP) | VAF 28/368 reads (8%) | called by muse, mutect2
- EPOR | c.873C>T p.S291= | Silent (SNP) | VAF 72/676 reads (11%) | catalogued as rs766932379; called by muse, mutect2, varscan2
- EYS | c.18C>A p.I6= | Silent (SNP) | VAF 25/204 reads (12%) | called by muse, mutect2, varscan2
- FAM193B | c.219C>T p.P73= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs767547329, COSV61557636; called by muse, mutect2, varscan2
- FAT1 | c.10308C>T p.N3436= | Silent (SNP) | VAF 28/268 reads (10%) | catalogued as rs745964428, COSV71672215; called by muse, mutect2, varscan2
- FMN2 | c.1500G>T p.A500= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV60451247; called by muse, mutect2
- FRMPD2 | c.1143C>A p.T381= | Silent (SNP) | VAF 103/419 reads (25%) | catalogued as COSV100563899, COSV59721419; called by muse, mutect2, varscan2
- GBP3 | c.675G>T p.R225= | Silent (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- GBP4 | c.1020G>A p.A340= | Silent (SNP) | VAF 32/309 reads (10%) | catalogued as rs780647917, COSV63254779; called by muse, mutect2, varscan2
- GFY | c.1461T>A p.P487= | Silent (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- GRIN2B | c.2493C>T p.L831= | Silent (SNP) | VAF 59/588 reads (10%) | called by muse, mutect2, varscan2
- HAPLN4 | c.699G>A p.L233= | Silent (SNP) | VAF 78/306 reads (25%) | catalogued as COSV52268556; called by muse, mutect2, varscan2
- HMCN1 | c.4281A>G p.G1427= | Silent (SNP) | VAF 55/404 reads (14%) | catalogued as rs998433413; called by muse, mutect2, varscan2
- IGHV4-39 | c.231G>C p.G77= | Silent (SNP) | VAF 208/801 reads (26%) | catalogued as rs762967894; called by muse, mutect2, varscan2
- IQSEC3 | c.306A>G p.A102= | Silent (SNP) | VAF 112/870 reads (13%) | called by muse, mutect2, varscan2
- ITGAV | c.2637G>T p.G879= | Silent (SNP) | VAF 35/324 reads (11%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.1083G>T p.T361= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV51527656; called by muse, mutect2, varscan2
- JPH4 | c.822C>A p.I274= | Silent (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- KAT6A | c.960A>G p.L320= | Silent (SNP) | VAF 51/262 reads (19%) | catalogued as rs747348896; called by muse, mutect2, varscan2
- KBTBD11 | c.1476G>A p.S492= | Silent (SNP) | VAF 19/286 reads (7%) | catalogued as rs772071058, COSV57224845; called by muse, mutect2
- KLHL14 | c.414G>T p.V138= | Silent (SNP) | VAF 38/146 reads (26%) | called by muse, mutect2
- LAMA5 | c.7485G>T p.L2495= | Silent (SNP) | VAF 65/356 reads (18%) | called by muse, mutect2, varscan2
- LTBP3 | c.3267G>T p.P1089= | Silent (SNP) | VAF 54/219 reads (25%) | called by muse, mutect2, varscan2
- LYST | c.1422T>C p.N474= | Silent (SNP) | VAF 74/308 reads (24%) | called by muse, mutect2, varscan2
- MAP3K19 | c.3624C>A p.A1208= | Silent (SNP) | VAF 39/154 reads (25%) | called by muse, mutect2, varscan2
- MELTF | c.513C>T p.S171= | Silent (SNP) | VAF 70/814 reads (9%) | catalogued as rs778982942, COSV56380195; called by muse, mutect2
- MICALL1 | c.2274C>T p.V758= | Silent (SNP) | VAF 26/418 reads (6%) | catalogued as rs752364347, COSV53239774, COSV53243092; called by muse, mutect2
- MUC16 | c.15405T>C p.H5135= | Silent (SNP) | VAF 41/281 reads (15%) | called by muse, mutect2, varscan2
- MYH11 | c.2247C>T p.L749= | Silent (SNP) | VAF 101/782 reads (13%) | catalogued as rs1268486209; called by muse, mutect2, varscan2
- MYH15 | c.4983A>G p.Q1661= | Silent (SNP) | VAF 55/104 reads (53%) | called by muse, mutect2, varscan2
- MYH6 | c.4584G>A p.L1528= | Silent (SNP) | VAF 130/665 reads (20%) | called by muse, mutect2, varscan2
- MYH7B | c.3432C>T p.D1144= | Silent (SNP) | VAF 40/437 reads (9%) | catalogued as rs960415013; called by muse, mutect2
- MYO5A | c.4959C>T p.I1653= | Silent (SNP) | VAF 58/339 reads (17%) | catalogued as rs756082685, COSV62560894; called by muse, mutect2, varscan2
- NIBAN1 | c.1269C>G p.L423= | Silent (SNP) | VAF 36/510 reads (7%) | catalogued as COSV62283428; called by muse, mutect2
- NR0B1 | c.1302C>T p.F434= | Silent (SNP) | VAF 64/344 reads (19%) | catalogued as rs866647367; called by muse, mutect2, varscan2
- OR2H2 | c.168A>T p.P56= | Silent (SNP) | VAF 27/184 reads (15%) | called by muse, mutect2, varscan2
- OR2T3 | c.204C>A p.I68= | Silent (SNP) | VAF 52/320 reads (16%) | called by muse, mutect2, varscan2
- OR51S1 | c.750C>T p.A250= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs774779619, COSV59057304; called by muse, varscan2
- OR5K3 | c.756C>A p.S252= | Silent (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- PELI2 | c.981C>T p.D327= | Silent (SNP) | VAF 15/392 reads (4%) | called by muse, mutect2
- PHF23 | c.975C>T p.D325= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs769502348, COSV50037516; called by muse, mutect2, varscan2
- PHLDA2 | c.285G>T p.A95= | Silent (SNP) | VAF 172/587 reads (29%) | catalogued as COSV56540628; called by muse, mutect2, varscan2
- PITPNC1 | c.309G>A p.P103= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as rs550357943, COSV55445322; called by muse, mutect2, varscan2
- POLK | c.1980G>A p.S660= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as rs145037174; called by muse, mutect2, varscan2
- POR | c.720C>T p.G240= | Silent (SNP) | VAF 25/205 reads (12%) | catalogued as rs374115833; called by muse, mutect2, varscan2
- POTEB3 | c.51A>G p.P17= | Silent (SNP) | VAF 79/722 reads (11%) | called by muse, mutect2, varscan2
- PRDM8 | c.180C>G p.L60= | Silent (SNP) | VAF 34/310 reads (11%) | catalogued as rs1359778779; called by muse, mutect2, varscan2
- PTF1A | c.693C>A p.G231= | Silent (SNP) | VAF 57/197 reads (29%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.1467T>C p.S489= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as rs1345894374; called by muse, mutect2, varscan2
- RCBTB2 | c.996C>T p.Y332= | Silent (SNP) | VAF 32/284 reads (11%) | called by muse, mutect2, varscan2
- REEP5 | c.387T>C p.P129= | Silent (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- RPGR | c.735G>T p.V245= | Silent (SNP) | VAF 95/228 reads (42%) | called by muse, mutect2, varscan2
- RTL1 | c.540C>G p.L180= | Silent (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- RYR1 | c.10554G>A p.L3518= | Silent (SNP) | VAF 192/735 reads (26%) | catalogued as rs778920000; called by muse, mutect2, varscan2
- SLC45A2 | c.1257G>A p.P419= | Silent (SNP) | VAF 44/601 reads (7%) | catalogued as rs989974325; called by muse, mutect2
- SLC6A13 | c.1296G>C p.L432= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as COSV100570105; called by muse, mutect2
- SMG7 | c.246G>A p.P82= | Silent (SNP) | VAF 37/395 reads (9%) | catalogued as rs372417959; called by muse, mutect2
- SRMS | c.237T>C p.C79= | Silent (SNP) | VAF 41/244 reads (17%) | called by muse, mutect2, varscan2
- SSC5D | c.1269G>A p.T423= | Silent (SNP) | VAF 18/263 reads (7%) | catalogued as rs372494888, COSV67477368; called by muse, mutect2
- STX4 | c.411C>T p.L137= | Silent (SNP) | VAF 48/390 reads (12%) | called by muse, mutect2, varscan2
- TRAV12-2 | c.258C>G p.L86= | Silent (SNP) | VAF 27/403 reads (7%) | called by muse, mutect2
- TRIM15 | c.51C>A p.T17= | Silent (SNP) | VAF 33/224 reads (15%) | called by muse, mutect2, varscan2
- TRMT61B | c.1275T>A p.I425= | Silent (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- USP24 | c.7233G>A p.S2411= | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as rs770624443, COSV99600276; called by muse, mutect2, varscan2
- XIRP2 | c.264G>A p.E88= (on ENST00000628543; = p.E263= on NM_152381.6) | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs751587508; called by muse, mutect2, varscan2
- XIRP2 | c.9024C>G p.V3008= (on ENST00000628543; = p.V3183= on NM_152381.6) | Silent (SNP) | VAF 32/274 reads (12%) | catalogued as rs1391268081; called by muse, mutect2, varscan2
- YBEY | c.81G>A p.R27= | Silent (SNP) | VAF 34/297 reads (11%) | called by muse, mutect2, varscan2
- ZNF254 | c.6A>T p.P2= | Silent (SNP) | VAF 90/377 reads (24%) | called by muse, mutect2, varscan2
- ZNF676 | c.1599A>T p.G533= (on ENST00000650058; = p.G501= on NM_001001411.3) | Silent (SNP) | VAF 72/321 reads (22%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.324G>A p.E108= | Silent (SNP) | VAF 88/246 reads (36%) | called by muse, mutect2, varscan2
- ZSCAN25 | c.1446C>T p.G482= | Silent (SNP) | VAF 19/297 reads (6%) | catalogued as rs367645804; called by muse, mutect2
- ZSWIM9 | c.1056G>A p.A352= | Silent (SNP) | VAF 55/434 reads (13%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-7179G>T | Intron (SNP) | VAF 46/153 reads (30%) | catalogued as rs1381886690; called by muse, mutect2, varscan2
- AC136604.1 | n.45C>A | RNA (SNP) | VAF 45/201 reads (22%) | called by muse, mutect2, varscan2
- ADAM6 | n.1450A>T | RNA (SNP) | VAF 69/390 reads (18%) | called by muse, mutect2, varscan2
- AKAP6 | c.*178A>G | 3'UTR (SNP) | VAF 60/229 reads (26%) | called by muse, mutect2, varscan2
- AMYP1 | n.607G>T | RNA (SNP) | VAF 58/544 reads (11%) | called by muse, mutect2, varscan2
- ARL9 | chr4:56505463 G>C | 5'Flank (SNP) | VAF 32/358 reads (9%) | called by muse, mutect2
- BRD2 | c.-35G>C | 5'UTR (SNP) | VAF 34/304 reads (11%) | called by muse, mutect2, varscan2
- BTNL3 | c.-48C>T | 5'UTR (SNP) | VAF 46/220 reads (21%) | called by muse, mutect2, varscan2
- C9orf163 | n.1473G>A | RNA (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- COPS3 | c.55+554C>A | Intron (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- DDX19B | chr16:70294911 G>A | 5'Flank (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- DMTN | c.*639C>T | 3'UTR (SNP) | VAF 32/190 reads (17%) | catalogued as rs763983163; called by muse, mutect2, varscan2
- FCRL2 | c.884-69C>A | Intron (SNP) | VAF 46/172 reads (27%) | called by muse, mutect2, varscan2
- FMR1 | c.*2143A>G | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- GRM1 | c.-13C>A | 5'UTR (SNP) | VAF 61/382 reads (16%) | catalogued as COSV51112951; called by mutect2, varscan2
- GSE1 | c.-63A>G | 5'UTR (SNP) | VAF 101/424 reads (24%) | called by muse, mutect2, varscan2
- HOOK3 | c.*8893T>C | 3'UTR (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- IL10RA | c.*1101T>G | 3'UTR (SNP) | VAF 44/179 reads (25%) | called by muse, mutect2, varscan2
- ISOC2 | c.349-25G>T | Intron (SNP) | VAF 65/225 reads (29%) | catalogued as rs1382665248, COSV99321202; called by muse, mutect2, varscan2
- KLHL2 | c.1754-668C>T | Intron (SNP) | VAF 47/163 reads (29%) | called by muse, mutect2, varscan2
- LEKR1 | c.264-32262C>T | Intron (SNP) | VAF 25/149 reads (17%) | catalogued as rs1262050539; called by muse, mutect2, varscan2
- LEXM | c.*8T>C | 3'UTR (SNP) | VAF 37/139 reads (27%) | catalogued as rs758650178; called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46109283 G>C | 5'Flank (SNP) | VAF 63/300 reads (21%) | called by muse, mutect2, varscan2
- MKS1 | c.916-16C>G | Intron (SNP) | VAF 91/361 reads (25%) | called by muse, mutect2, varscan2
- MTCL1 | c.2967+22C>T | Intron (SNP) | VAF 46/189 reads (24%) | catalogued as rs761812663; called by mutect2, varscan2
- MUC19 | n.5517G>T | RNA (SNP) | VAF 31/342 reads (9%) | called by muse, mutect2
- PCCB | c.1199-44A>T | Intron (SNP) | VAF 128/601 reads (21%) | called by muse, mutect2, varscan2
- PCNT | c.*30A>G | 3'UTR (SNP) | VAF 40/320 reads (13%) | catalogued as rs780468253; called by muse, mutect2, varscan2
- PRORY | n.104A>T | RNA (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- PTPRM | c.2528-728G>T | Intron (SNP) | VAF 48/227 reads (21%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158911 C>T | 5'Flank (SNP) | VAF 101/419 reads (24%) | catalogued as rs781289403; called by muse, mutect2, varscan2
- RPL34 | c.-4C>A | 5'UTR (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- SHOX | c.*21C>A | 3'UTR (SNP) | VAF 16/176 reads (9%) | catalogued as rs747422624; called by muse, mutect2
- SIVA1 | c.-31G>A | 5'UTR (SNP) | VAF 25/324 reads (8%) | catalogued as rs755417543; called by muse, mutect2
- SNORD115-16 | n.32A>T | RNA (SNP) | VAF 32/456 reads (7%) | called by muse, mutect2
- SPAG11B | c.*87C>T | 3'UTR (SNP) | VAF 76/839 reads (9%) | catalogued as rs747539041, COSV99872978; called by muse, mutect2
- SPATA8 | n.286C>G | RNA (SNP) | VAF 25/267 reads (9%) | catalogued as COSV60705403; called by muse, mutect2
- TBC1D1 | c.1911-1000C>A | Intron (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- TPI1 | c.*330A>T | 3'UTR (SNP) | VAF 148/535 reads (28%) | called by muse, mutect2, varscan2
- TRPM8 | c.*61G>T | 3'UTR (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
- UCHL3 | c.475-4809C>T | Intron (SNP) | VAF 40/134 reads (30%) | called by muse, mutect2, varscan2
- ZDHHC13 | c.-81G>C | 5'UTR (SNP) | VAF 44/197 reads (22%) | called by muse, mutect2, varscan2
- ZNF99 | c.*1042G>T | 3'UTR (SNP) | VAF 25/160 reads (16%) | catalogued as COSV68055930; called by muse, mutect2, varscan2
